Somatic mutation profile of tumor specimen TARGET-10-PATMRE-09A (aliquot TARGET-10-PATMRE-09A-01D) from TARGET case TARGET-10-PATMRE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,472 days).
Specimen TARGET-10-PATMRE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5151a4e1-858c-44f3-aaaf-fdd20da836ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATMRE-10A (Blood Derived Normal), aliquot TARGET-10-PATMRE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97d20246-0af4-427c-9856-452b43069ef6

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 5'UTR 3, Silent 2, Frame Shift Ins 2, Intron 2, Frame Shift Del 1, 3'UTR 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.403A>G p.R135G (on ENST00000344691 / NM_001001890.3; = p.R162G on NM_001754.5) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519751, COSV55867213; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRE2 | c.833T>A p.L278H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV59696401; called by muse, mutect2, varscan2
- AMELX | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT tolerated (0.36); PolyPhen benign (0.061); catalogued as rs773277711, COSV61629275; called by muse, mutect2, varscan2
- BCL6 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.451); catalogued as rs375595181; called by muse, mutect2, varscan2
- BRINP1 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as COSV56294847; called by muse, mutect2, varscan2
- COPB1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51448329; called by muse, mutect2, varscan2
- DCTN1 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs121909344, CM042336; ClinVar: uncertain significance / risk factor; called by muse, mutect2, varscan2
- DNM2 | c.820_821insAGAGGGCTC p.T274delinsKRAP | In Frame Ins (INS) | VAF 11/47 reads (23%) | catalogued as COSV58972028; called by mutect2, pindel, varscan2
- INO80 | c.3634C>T p.R1212C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62739466; called by muse, mutect2, varscan2
- JAK3 | c.2021T>C p.V674A | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV71685576; called by muse, mutect2, varscan2
- KIF2B | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769176818, COSV52126857; called by muse, mutect2
- NARF | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV59113701; called by muse, mutect2, varscan2
- NIPSNAP3A | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV66113718; called by muse, mutect2, varscan2
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2, varscan2
- PSD2 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs547591794, COSV51211147; called by muse, varscan2
- RFPL4B | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1207905288, COSV71437500; called by muse, mutect2, varscan2
- SHOX2 | c.676G>C p.G226R (on ENST00000441443 / NM_006884.3; = p.G250R on NM_003030.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67464787; called by muse, mutect2, varscan2
- TRA2B | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV52026393, COSV99373280; called by muse, mutect2, varscan2
- TTC6 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.463); catalogued as rs552758844, COSV73284743; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs533279858, COSV51960607; called by muse, mutect2, varscan2
- DNAJB12 | c.1125_1126insAACCCCCTTATGAA p.R376Nfs*69 (on ENST00000338820; = p.R342Nfs*52 on NM_017626.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 25/58 reads (43%) | called by mutect2, pindel*, varscan2*
- IRF1 | c.314_315del p.A105Gfs*27 | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | called by pindel*, varscan2
- ITGA8 | c.2076A>G p.I692M | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ITGA8 | c.2075T>C p.I692T | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PICALM | c.48dup p.V17Cfs*35 | Frame Shift Ins (INS) | VAF 20/29 reads (69%) | called by mutect2, pindel, varscan2
- ITPRIPL2 | c.627C>T p.C209= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs200493379; called by muse, mutect2, varscan2
- WWC1 | c.2157C>T p.D719= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as rs765927561; called by muse, mutect2
- CENATAC | c.383+30C>G | Intron (SNP) | VAF 21/36 reads (58%) | catalogued as rs1013312169; called by muse, mutect2, varscan2
- LPO | c.781-435A>C | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- MAG | c.-47C>T | 5'UTR (SNP) | VAF 31/66 reads (47%) | catalogued as rs1242941196; called by muse, mutect2
- SEMA4D | c.-57C>T | 5'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as rs752589829, COSV100358820; called by muse, mutect2, varscan2
- SHTN1 | c.*2230G>A | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- SLC25A21 | c.-5C>T | 5'UTR (SNP) | VAF 27/48 reads (56%) | catalogued as rs1204667819; called by muse, mutect2, varscan2
- YBX1P1 | n.349A>G | RNA (SNP) | VAF 4/21 reads (19%) | catalogued as rs878979795; called by muse, varscan2
